Gene-level copy-number profile of tumor specimen TCGA-MT-A51W-01A from TCGA case TCGA-MT-A51W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.3 years (19,098 days).
Specimen TCGA-MT-A51W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c7c359de-871b-4d78-8345-5a4b597175e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MT-A51W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/937eadfb-3eda-4acc-b4e1-b15782ffec49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 9,124; copy number 2: 44,413; copy number 3: 4,060; copy number 4: 1,549; copy number 5: 114; copy number 6: 45; copy number 7: 220; copy number 8: 127; copy number 10: 96; copy number 11: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MT-A51W-01A-21D-A25X-01): tumor purity 0.22, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–424,059, 11 genes: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 658 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:63,774,017–65,092,614, 23 genes, copy number 5: ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1.
- chr7:75,533,298–75,738,962, 1 gene, copy number 5 (within-gene range 3–5): HIP1.
- chr7:75,769,533–86,217,733, 130 genes, copy number 5–11 (broad region; genes not listed).
- chr7:86,782,357–104,208,047, 409 genes, copy number 7–11 (broad region; genes not listed).
- chr11:68,870,664–71,928,654, 95 genes, copy number 6–8 (within-gene range 1–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,703. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
